MMRF case MMRF_1533 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/9c3c8e77-676c-4bc4-9c29-8511d0528e71

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 65 years; Vital status: Dead; Days to death: 763 days (2.1 years); Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 65.7 years (24,012 days); ISS stage: III; Days to last known disease status: 763 days (2.1 years); Days to last follow up: 763 days (2.1 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 398 days (1.1 years).
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 189 days; Days to treatment end: 189 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 399 days (1.1 years); Days to treatment end: 567 days (1.6 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 581 days (1.6 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 763.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -7 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 474 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.74 mg/dL; Immunoglobulin G 6.26 g/L; Immunoglobulin A 0.59 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 9.97 µg/mL; Hemoglobin 4.84 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 7.39 ×10⁹/L; Platelets 146 ×10⁹/L; Creatinine 243 µmol/L; Blood Urea Nitrogen 14.6 mmol/L; Calcium 2.38 mmol/L; Albumin 46 g/L; Glucose 6.22 mmol/L; C-Reactive Protein 0.067 mg/dL.
- Day 70 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 147 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.62 mg/dL; Immunoglobulin G 4.52 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 4.18 µkat/L; Hemoglobin 6.01 mmol/L; Leukocytes 10.6 ×10⁹/L; Absolute Neutrophil 9.35 ×10⁹/L; Platelets 263 ×10⁹/L; Creatinine 148 µmol/L; Blood Urea Nitrogen 13.2 mmol/L; Calcium 2.4 mmol/L; Albumin 45 g/L; Total Protein 6.3 g/dL; Glucose 9.79 mmol/L.
- Day 168 (ECOG 1): M Protein 5.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 92.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.73 mg/dL; Immunoglobulin G 3.79 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 0.7 µg/mL; Hemoglobin 6.39 mmol/L; Leukocytes 7.5 ×10⁹/L; Absolute Neutrophil 4.73 ×10⁹/L; Platelets 240 ×10⁹/L; Creatinine 157 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.4 mmol/L; Albumin 40 g/L; Total Protein 5.9 g/dL; Glucose 7.7 mmol/L.
- Day 245 (ECOG 1): M Protein 5.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.94 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.85 mg/dL; Immunoglobulin G 4.03 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 2.98 µkat/L; Hemoglobin 5.7 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 4.39 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 149 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.25 mmol/L; Albumin 36 g/L; Total Protein 5.7 g/dL; Glucose 5.72 mmol/L.
- Day 364 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.28 mg/dL; Immunoglobulin G 7 g/L; Immunoglobulin A 0.77 g/L; Immunoglobulin M 0.25 g/L; Hemoglobin 5.95 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 4.61 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 117 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.25 mmol/L; Albumin 39 g/L; Total Protein 6.1 g/dL; Glucose 6.22 mmol/L.
- Day 448 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 10.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.21 mg/dL; Immunoglobulin G 6.94 g/L; Immunoglobulin A 0.57 g/L; Immunoglobulin M 0.25 g/L; Hemoglobin 6.57 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 4.54 ×10⁹/L; Platelets 150 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 6.2 g/dL; Glucose 5.45 mmol/L.
- Day 511 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 99.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.76 mg/dL; Immunoglobulin G 6.25 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 0.25 g/L; Hemoglobin 6.08 mmol/L; Leukocytes 8.2 ×10⁹/L; Absolute Neutrophil 6.07 ×10⁹/L; Platelets 141 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 11.1 mmol/L; Calcium 2.48 mmol/L; Albumin 42 g/L; Total Protein 6.5 g/dL; Glucose 6.66 mmol/L.

Other clinical attributes
- Day -7: Weight: 101 kg; Height: 193 cm.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples)
- Sample MMRF_1533_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -7 days.
- Sample MMRF_1533_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -7 days.
- Sample MMRF_1533_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 594 days (1.6 years).
